Somatic mutation profile of tumor specimen TCGA-CR-6482-01A (aliquot TCGA-CR-6482-01A-11D-1870-08) from TCGA case TCGA-CR-6482, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; Tumor grade: G3; Age at diagnosis: 62.3 years (22,741 days).
Specimen TCGA-CR-6482-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e17d8b48-77a1-4e3e-9c82-bf8d13744d36.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-6482-10A (Blood Derived Normal), aliquot TCGA-CR-6482-10A-01D-1870-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5490ace7-9701-4e20-8b81-bbe3b13ecec5

The open-access MAF lists 45 somatic variants for this specimen: 34 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 32, Silent 11, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PRICKLE1 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as rs781255236, COSV100566406; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ARL14EP | c.720G>T p.K240N | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.229); catalogued as COSV99955952; called by muse, mutect2, varscan2
- CDC42EP1 | c.360C>G p.I120M | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.88); catalogued as COSV99312498; called by muse, mutect2, varscan2
- CHODL | c.226G>C p.E76Q | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV100166832; called by muse, mutect2, varscan2
- CHST11 | c.713A>G p.E238G | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.245); catalogued as rs1459696154, COSV100359491; called by muse, mutect2, varscan2
- CSF1 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.82); PolyPhen benign (0.015); catalogued as rs771970619, COSV100294550; called by muse, mutect2, varscan2
- CYP4F12 | c.1520G>A p.R507H | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV61175570; called by muse, mutect2, varscan2
- DST | c.6029T>A p.L2010Q | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99756479; called by muse, mutect2, varscan2
- GFRAL | c.952+2T>C p.X318_splice | Splice Site (SNP) | VAF 8/53 reads (15%) | catalogued as COSV100475226; called by muse, mutect2, varscan2
- GNG8 | c.89C>A p.S30* | Nonsense Mutation (SNP) | VAF 7/18 reads (39%) | catalogued as COSV100340084; called by muse, mutect2, varscan2
- GRIN2D | c.1859A>G p.K620R | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as COSV99616495; called by muse, mutect2, varscan2
- KALRN | c.1820C>T p.T607M | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99562445, COSV99564729; called by muse, mutect2, varscan2
- KIAA1549 | c.2401G>A p.E801K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV99650869; called by muse, mutect2, varscan2
- KRT33A | c.1160C>A p.S387Y | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.139); catalogued as COSV99144892; called by muse, mutect2
- LRRC30 | c.41G>A p.G14D | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as COSV101274416; called by muse, mutect2, varscan2
- LRRK1 | c.3424G>A p.D1142N | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as COSV52626716, COSV99440336; called by muse, mutect2, varscan2
- LRSAM1 | c.1871G>A p.R624Q | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as rs775743246, COSV100031545; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYB | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100214885; called by muse, mutect2, varscan2
- NID2 | c.3884C>T p.T1295I | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV53497597, COSV99356602; called by muse, mutect2, varscan2
- NRBP2 | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as COSV100589220; called by muse, mutect2, varscan2
- PA2G4 | c.1101G>C p.Q367H | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV57570256; called by muse, mutect2, varscan2
- PABPC3 | c.151T>C p.S51P | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as COSV99879535; called by muse, mutect2, varscan2
- PLEC | c.6338C>T p.A2113V (on ENST00000322810 / NM_201380.4; = p.A2003V on NM_000445.5) | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.996); catalogued as rs781911978, COSV100514551; called by muse, mutect2, varscan2
- PRG2 | c.644G>T p.R215I | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.61); catalogued as COSV100314927; called by muse, mutect2, varscan2
- RARRES2 | c.292T>G p.C98G | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99784662; called by muse, varscan2
- RASGRP3 | c.1265G>T p.R422M (on ENST00000402538 / NM_001349975.2; = p.R421M on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV101274761; called by muse, mutect2
- RGL4 | c.1130G>A p.R377K | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs1445527033, COSV99318757; called by muse, mutect2, varscan2
- RYR3 | c.14123G>A p.C4708Y (on ENST00000389232; = p.C4709Y on NM_001036.6) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66781952; called by muse, mutect2, varscan2
- SLF2 | c.2196T>G p.I732M | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.295); catalogued as COSV99489238; called by muse, mutect2, varscan2
- TAF7 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT tolerated (0.85); PolyPhen benign (0.026); catalogued as COSV100514997; called by muse, mutect2, varscan2
- TANC2 | c.1109G>A p.G370E | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV101267455; called by muse, mutect2, varscan2
- TPSD1 | c.264G>C p.K88N | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.261); catalogued as rs1276355751, COSV52973991; called by muse, mutect2
- UBA3 | c.752A>T p.E251V | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100734694; called by muse, mutect2, varscan2
- ZNF543 | c.155T>C p.L52S | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as COSV100386789; called by muse, mutect2, varscan2
- FASN | c.3123G>A p.S1041= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as rs146226779; called by muse, mutect2, varscan2
- FBXO44 | c.378C>T p.F126= | Silent (SNP) | VAF 32/121 reads (26%) | catalogued as COSV52353624; called by muse, mutect2, varscan2
- FIBCD1 | c.423C>T p.A141= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs748083505, COSV99447131; called by muse, varscan2
- GPRC6A | c.606G>C p.L202= | Silent (SNP) | VAF 58/251 reads (23%) | catalogued as COSV100114409; called by muse, mutect2, varscan2
- HRNR | c.5598T>A p.G1866= | Silent (SNP) | VAF 74/1478 reads (5%) | catalogued as COSV100913512; called by muse, mutect2
- MAP1A | c.3297C>A p.V1099= | Silent (SNP) | VAF 21/106 reads (20%) | catalogued as COSV55807811; called by muse, mutect2, varscan2
- MPPE1 | c.360C>A p.I120= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as COSV100013257; called by muse, mutect2, varscan2
- MYO15A | c.7986G>A p.L2662= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV99233013; called by muse, mutect2
- PCDH12 | c.3177G>A p.A1059= | Silent (SNP) | VAF 22/93 reads (24%) | catalogued as rs375614422; called by muse, mutect2, varscan2
- TRIM46 | c.1545C>T p.G515= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs755781278, COSV58116239; called by muse, mutect2, varscan2
- VPS18 | c.564C>G p.L188= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as COSV99592512; called by muse, mutect2, varscan2
